Somatic mutation profile of cancer-model specimen HCM-BROD-0008-C25-85A (3D Organoid, passage 11; aliquot HCM-BROD-0008-C25-85A-01D-A786-36), derived from the metastatic tumor of HCMI case HCM-BROD-0008-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 63.5 years (23,186 days).
Specimen HCM-BROD-0008-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2ccdd2a-426d-4c08-a9e5-a0c9236697ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0008-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0008-C25-10A-01D-A78W-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2e70ae4-109d-464d-8579-649e4cfab667

The open-access MAF lists 135 somatic variants for this specimen: 95 protein-altering or splice-affecting, 22 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 22, Intron 8, Nonsense Mutation 7, Frame Shift Del 6, RNA 4, Frame Shift Ins 3, 3'UTR 3, 3'Flank 2, Splice Site 2, Nonstop Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 164/245 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 423/424 reads (100%) | hotspot (GDC flag); catalogued as COSV52666332, COSV52700326, COSV52746468; called by muse, mutect2, varscan2
- ABCA3 | c.995A>C p.K332T | Missense Mutation (SNP) | VAF 78/204 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV57054013; called by muse, mutect2, varscan2
- ALDH1L1 | c.2599G>A p.D867N | Missense Mutation (SNP) | VAF 137/814 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs775642396; called by muse, mutect2, varscan2
- ARAP3 | c.2507C>G p.S836* | Nonsense Mutation (SNP) | VAF 29/118 reads (25%) | catalogued as COSV53348420; called by muse, mutect2, varscan2
- B3GALT2 | c.83T>C p.I28T | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs555499650; called by muse, mutect2, varscan2
- BICC1 | c.2516G>A p.R839H | Missense Mutation (SNP) | VAF 114/404 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs200282277; called by muse, mutect2, varscan2
- DSCAM | c.948del p.T317Pfs*21 | Frame Shift Del (DEL) | VAF 43/160 reads (27%) | catalogued as COSV68027109; called by mutect2, pindel, varscan2
- FLAD1 | c.218dup p.C74Vfs*28 | Frame Shift Ins (INS) | VAF 27/104 reads (26%) | catalogued as rs772370005; called by mutect2, pindel, varscan2
- GOLGA6L22 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 248/349 reads (71%) | SIFT tolerated (0.14); PolyPhen benign (0.225); catalogued as rs1459454497; called by mutect2, varscan2
- KRT81 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 77/640 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.344); catalogued as rs760791254; called by muse, mutect2, varscan2
- KRTAP2-4 | c.191G>A p.C64Y | Missense Mutation (SNP) | VAF 43/321 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as rs1161588095, COSV67458617; called by muse, mutect2, varscan2
- LAMC3 | c.2816G>T p.R939L | Missense Mutation (SNP) | VAF 135/490 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as rs777019483; called by muse, mutect2, varscan2
- LRP1B | c.11954G>A p.W3985* | Nonsense Mutation (SNP) | VAF 91/289 reads (31%) | catalogued as COSV67232700, COSV67256675; called by muse, mutect2, varscan2
- LY75-CD302 | c.5622A>C p.*1874Yext*? | Nonstop Mutation (SNP) | VAF 18/64 reads (28%) | catalogued as rs1346939051, COSV99374197; called by muse, mutect2, varscan2
- MAGEA3 | c.640G>T p.D214Y | Missense Mutation (SNP) | VAF 129/888 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV64755972; called by muse, mutect2, varscan2
- NEB | c.13439T>C p.I4480T | Missense Mutation (SNP) | VAF 82/320 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs764500250; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NTSR1 | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 216/450 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as rs754914970; called by muse, mutect2, varscan2
- OR10J1 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 97/341 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV71129224; called by muse, mutect2, varscan2
- PTPRG | c.1552G>A p.G518S | Missense Mutation (SNP) | VAF 80/223 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs764776482, COSV55640529; called by muse, mutect2, varscan2
- RABEP2 | c.465C>G p.I155M | Missense Mutation (SNP) | VAF 84/262 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV62869584; called by muse, mutect2, varscan2
- RAE1 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64798027; called by muse, mutect2, varscan2
- SFSWAP | c.2297G>A p.R766Q | Missense Mutation (SNP) | VAF 88/265 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.978); catalogued as rs1441863628, COSV55523363; called by muse, mutect2, varscan2
- SLC28A1 | c.280C>T p.L94F | Missense Mutation (SNP) | VAF 201/560 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1037805732, COSV54483325; called by muse, mutect2, varscan2
- SLC9A1 | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs754510627; called by muse, mutect2, varscan2
- SNAPC4 | c.2731A>G p.T911A | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV100047730; called by muse, mutect2, varscan2
- STAB1 | c.3862C>T p.Q1288* | Nonsense Mutation (SNP) | VAF 38/143 reads (27%) | catalogued as rs1206217550; called by muse, mutect2, varscan2
- TAS1R3 | c.1957del p.L653Cfs*14 | Frame Shift Del (DEL) | VAF 140/515 reads (27%) | catalogued as COSV104411930; called by mutect2, pindel, varscan2
- ZBED6 | c.1808A>T p.E603V | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV59745634; called by muse, mutect2, varscan2
- A4GALT | c.998T>A p.L333Q | Missense Mutation (SNP) | VAF 88/339 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ADAM7 | c.2209-2A>G p.X737_splice | Splice Site (SNP) | VAF 30/75 reads (40%) | called by muse, mutect2, varscan2
- AKT1S1 | c.502T>A p.S168T (on ENST00000344175 / NM_001098633.4; = p.S188T on NM_032375.5) | Missense Mutation (SNP) | VAF 63/216 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ANKRD12 | c.2591T>A p.V864D | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ARHGEF40 | c.2385G>T p.W795C | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ARMCX5 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 147/232 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- B3GALT2 | c.578T>G p.L193* | Nonsense Mutation (SNP) | VAF 28/90 reads (31%) | called by muse, mutect2, varscan2
- BRD1 | c.1954G>A p.A652T | Missense Mutation (SNP) | VAF 300/529 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CDK12 | c.1801T>A p.S601T | Missense Mutation (SNP) | VAF 77/325 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CELSR3 | c.3991T>C p.S1331P | Missense Mutation (SNP) | VAF 116/374 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CIB2 | c.257T>G p.L86R | Missense Mutation (SNP) | VAF 115/330 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- CLSTN3 | c.51_64+7del p.X17_splice | Splice Site (DEL) | VAF 219/466 reads (47%) | called by mutect2, pindel, varscan2
- CNGA2 | c.1453G>C p.G485R | Missense Mutation (SNP) | VAF 151/390 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTN3 | c.850A>C p.I284L | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- DCHS1 | c.6295A>G p.N2099D | Missense Mutation (SNP) | VAF 80/329 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- DOCK5 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DOCK7 | c.4227A>C p.E1409D (on ENST00000635253 / NM_001367561.1; = p.E1378D on NM_033407.3) | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- DSPP | c.261A>T p.E87D | Missense Mutation (SNP) | VAF 79/170 reads (46%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- FBXW11 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 94/156 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FGD3 | c.927C>G p.D309E | Missense Mutation (SNP) | VAF 53/209 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- GLRA1 | c.1335C>G p.I445M (on ENST00000455880 / NM_001146040.2; = p.I437M on NM_000171.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 97/290 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- GLRA4 | c.905G>A p.S302N | Missense Mutation (SNP) | VAF 147/984 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- IGKV1D-33 | c.147G>T p.Q49H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.246); called by mutect2, varscan2
- IRS4 | c.2375dup p.N792Kfs*33 | Frame Shift Ins (INS) | VAF 245/825 reads (30%) | called by mutect2, pindel, varscan2
- KALRN | c.2882A>G p.Q961R | Missense Mutation (SNP) | VAF 133/657 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KIF21B | c.3407A>C p.K1136T | Missense Mutation (SNP) | VAF 92/356 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- KTN1 | c.3592G>C p.D1198H (on ENST00000395314 / NM_001271014.2; = p.D1169H on NM_004986.4) | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- LILRA5 | c.700A>T p.I234F | Missense Mutation (SNP) | VAF 150/518 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- LONP2 | c.577A>T p.T193S | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MCF2 | c.2206dup p.C736Lfs*6 | Frame Shift Ins (INS) | VAF 80/542 reads (15%) | called by mutect2, pindel, varscan2
- MCM5 | c.642_644del p.I214del | In Frame Del (DEL) | VAF 90/198 reads (45%) | called by pindel, varscan2
- MEGF10 | c.216C>G p.H72Q | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- MRC2 | c.2905C>A p.L969M | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- MROH9 | c.77A>T p.H26L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC19 | c.359A>T p.K120M | Missense Mutation (SNP) | VAF 67/193 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MYBBP1A | c.2846A>C p.K949T | Missense Mutation (SNP) | VAF 101/200 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- MYLK | c.4242G>T p.E1414D | Missense Mutation (SNP) | VAF 115/456 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- NLRP10 | c.1123T>A p.L375I | Missense Mutation (SNP) | VAF 87/255 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- NOX3 | c.1468G>C p.A490P | Missense Mutation (SNP) | VAF 72/192 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- OR10G7 | c.662T>G p.V221G | Missense Mutation (SNP) | VAF 95/298 reads (32%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- PCYT1A | c.300G>C p.K100N | Missense Mutation (SNP) | VAF 65/375 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPFIBP1 | c.220A>G p.I74V | Missense Mutation (SNP) | VAF 127/505 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRDM14 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- RNF213 | c.3965A>C p.K1322T | Missense Mutation (SNP) | VAF 77/377 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- RPAP1 | c.3972+4A>C | Splice Region (SNP) | VAF 58/217 reads (27%) | called by muse, mutect2, varscan2
- SENP5 | c.1313A>G p.N438S | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC8A3 | c.994T>G p.L332V | Missense Mutation (SNP) | VAF 163/578 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SNURF | c.174A>T p.E58D | Missense Mutation (SNP) | VAF 185/536 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- STAB2 | c.4565G>T p.G1522V | Missense Mutation (SNP) | VAF 93/302 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STT3B | c.1253del p.L418Hfs*39 | Frame Shift Del (DEL) | VAF 93/174 reads (53%) | called by mutect2, pindel, varscan2
- TECR | c.587_588del p.L196Rfs*119 | Frame Shift Del (DEL) | VAF 492/1254 reads (39%) | called by mutect2, pindel, varscan2
- TEX13C | c.2452A>T p.K818* | Nonsense Mutation (SNP) | VAF 453/800 reads (57%) | called by muse, mutect2, varscan2
- TG | c.8062T>G p.F2688V | Missense Mutation (SNP) | VAF 172/694 reads (25%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- THNSL1 | c.931G>T p.G311* | Nonsense Mutation (SNP) | VAF 160/277 reads (58%) | called by muse, mutect2, varscan2
- TMEM132A | c.1153A>C p.M385L (on ENST00000453848 / NM_178031.3; = p.M386L on NM_017870.4) | Missense Mutation (SNP) | VAF 123/392 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- TMEM151B | c.1121A>T p.E374V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TOPBP1 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 175/311 reads (56%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- TRIM56 | c.1571C>T p.A524V | Missense Mutation (SNP) | VAF 130/200 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TRPC5 | c.269del p.L90Rfs*41 | Frame Shift Del (DEL) | VAF 92/580 reads (16%) | called by mutect2, pindel*, varscan2
- TSPAN5 | c.596A>G p.Q199R | Missense Mutation (SNP) | VAF 67/164 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UGT3A1 | c.1133C>A p.A378D | Missense Mutation (SNP) | VAF 102/254 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- WHAMM | c.545C>G p.P182R | Missense Mutation (SNP) | VAF 79/228 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF155 | c.1328T>C p.L443P | Missense Mutation (SNP) | VAF 78/264 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF551 | c.1018_1027del p.C340Pfs*148 | Frame Shift Del (DEL) | VAF 48/261 reads (18%) | called by mutect2, pindel, varscan2
- ZPBP2 | c.503A>C p.K168T (on ENST00000348931 / NM_199321.3; = p.K146T on NM_198844.3) | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- ZRANB3 | c.554T>G p.L185R | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD109 | c.1977A>G p.E659= | Silent (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2
- CFAP251 | c.3066C>T p.I1022= | Silent (SNP) | VAF 34/105 reads (32%) | catalogued as rs187982927; called by muse, mutect2, varscan2
- CNTNAP4 | c.1938T>C p.N646= | Silent (SNP) | VAF 62/74 reads (84%) | catalogued as COSV56670463; called by muse, mutect2, varscan2
- DCBLD2 | c.939G>A p.V313= | Silent (SNP) | VAF 145/729 reads (20%) | called by muse, mutect2, varscan2
- DKK2 | c.448C>A p.R150= | Silent (SNP) | VAF 144/144 reads (100%) | catalogued as rs1254069801, COSV53397188, COSV53400080; called by muse, mutect2, varscan2
- DMWD | c.1035C>T p.G345= | Silent (SNP) | VAF 137/212 reads (65%) | catalogued as rs142998214; called by muse, mutect2, varscan2
- FGFRL1 | c.6G>A p.T2= | Silent (SNP) | VAF 101/210 reads (48%) | catalogued as rs1246707687; called by muse, mutect2, varscan2
- FLT4 | c.2553C>T p.L851= | Silent (SNP) | VAF 122/178 reads (69%) | catalogued as rs756742987; called by muse, mutect2, varscan2
- IL16 | c.156C>A p.G52= | Silent (SNP) | VAF 95/242 reads (39%) | called by muse, mutect2, varscan2
- LIFR | c.1569C>T p.S523= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as rs767207879; called by muse, mutect2, varscan2
- NOL8 | c.1350C>T p.P450= | Silent (SNP) | VAF 68/208 reads (33%) | catalogued as rs1461897210; called by muse, mutect2, varscan2
- OR13G1 | c.720T>G p.S240= | Silent (SNP) | VAF 51/136 reads (38%) | catalogued as COSV62944660, COSV62944925; called by muse, mutect2, varscan2
- OR2H1 | c.570C>A p.T190= | Silent (SNP) | VAF 67/237 reads (28%) | called by muse, mutect2, varscan2
- PCBP4 | c.894C>T p.I298= (on ENST00000322099 / NM_033010.2; = p.I255= on NM_020418.4) | Silent (SNP) | VAF 102/150 reads (68%) | catalogued as rs199654401; called by muse, mutect2, varscan2
- PCDHA8 | c.1914C>T p.D638= | Silent (SNP) | VAF 168/531 reads (32%) | catalogued as rs782176303, COSV65332432; called by muse, mutect2, varscan2
- PCDHGA2 | c.1965C>T p.S655= | Silent (SNP) | VAF 196/668 reads (29%) | catalogued as rs771072942, COSV99541905; called by muse, mutect2, varscan2
- RALGDS | c.261C>T p.H87= | Silent (SNP) | VAF 15/474 reads (3%) | catalogued as rs936757649; called by muse, mutect2
- TAF1A | c.387C>T p.G129= | Silent (SNP) | VAF 34/147 reads (23%) | catalogued as rs1438915794, COSV61919983; called by muse, mutect2, varscan2
- TAF7L | c.138C>T p.S46= | Silent (SNP) | VAF 387/1118 reads (35%) | called by muse, mutect2, varscan2
- UGT3A1 | c.1134C>T p.A378= | Silent (SNP) | VAF 103/259 reads (40%) | catalogued as rs762050381; called by muse, mutect2, varscan2
- USP13 | c.969G>T p.S323= | Silent (SNP) | VAF 62/368 reads (17%) | catalogued as COSV99831071, COSV99831916; called by muse, mutect2, varscan2
- ZIM2 | c.837G>A p.P279= | Silent (SNP) | VAF 64/176 reads (36%) | catalogued as rs191866455, COSV55639172; called by muse, mutect2, varscan2
- AC064807.1 | n.2759C>T | RNA (SNP) | VAF 55/120 reads (46%) | called by muse, mutect2, varscan2
- APTX | c.134-11A>G | Intron (SNP) | VAF 42/171 reads (25%) | catalogued as rs375978921; called by muse, mutect2, varscan2
- ARSB | c.1213+23258G>A | Intron (SNP) | VAF 112/230 reads (49%) | catalogued as rs995643493; called by muse, mutect2, varscan2
- BMERB1 | c.106+13216C>T | Intron (SNP) | VAF 23/130 reads (18%) | catalogued as rs1445454370; called by muse, mutect2, varscan2
- CALY | c.246+91G>A | Intron (SNP) | VAF 164/251 reads (65%) | called by muse, mutect2, varscan2
- CC2D2B | chr10:96032707 del AAAAGTTTGCACTTTGGATGCTACTGACATG | 3'Flank (DEL) | VAF 32/53 reads (60%) | called by mutect2, pindel
- CPS1 | c.3667-20G>A | Intron (SNP) | VAF 59/250 reads (24%) | catalogued as rs369845787; called by muse, mutect2, varscan2
- DPP10 | c.61-147015C>T | Intron (SNP) | VAF 108/312 reads (35%) | catalogued as rs756659116; called by muse, mutect2, varscan2
- DYNC1H1 | c.*46A>C | 3'UTR (SNP) | VAF 91/274 reads (33%) | called by muse, mutect2, varscan2
- GLRXP3 | n.308G>A | RNA (SNP) | VAF 78/236 reads (33%) | called by muse, mutect2, varscan2
- KRT18P55 | n.1098A>G | RNA (SNP) | VAF 113/434 reads (26%) | called by muse, mutect2, varscan2
- NPC1 | c.3591+47T>C | Intron (SNP) | VAF 62/2652 reads (2%) | called by muse, mutect2
- OR2U1P | n.595T>G | RNA (SNP) | VAF 25/72 reads (35%) | called by muse, mutect2, varscan2
- RADIL | c.2291-19C>T | Intron (SNP) | VAF 148/433 reads (34%) | called by muse, mutect2, varscan2
- RPL10 | c.*3G>C | 3'UTR (SNP) | VAF 154/749 reads (21%) | catalogued as COSV99186411; called by muse, mutect2, varscan2
- SYT14 | chr1:210163234 C>G | 3'Flank (SNP) | VAF 61/94 reads (65%) | called by muse, mutect2, varscan2
- UMPS | c.*644dup | 3'UTR (INS) | VAF 45/225 reads (20%) | called by mutect2, pindel, varscan2
- Unknown | chr17:43379201 C>T | IGR (SNP) | VAF 160/382 reads (42%) | called by muse, mutect2, varscan2
